Somatic mutation profile of tumor specimen TCGA-61-1722-01A (aliquot TCGA-61-1722-01A-01D-1556-09) from TCGA case TCGA-61-1722, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-61-1722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a25ef9d-043e-4953-9764-06fc9c02aad4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1722-11A (Solid Tissue Normal), aliquot TCGA-61-1722-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a72b104e-5260-412d-bf9b-58cc71b268eb

The open-access MAF lists 94 somatic variants for this specimen: 73 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 20, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 27/40 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.5980G>A p.G1994S | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV54967636; called by muse, mutect2, varscan2
- AHCTF1 | c.3046G>C p.D1016H (on ENST00000366508; = p.D990H on NM_015446.5) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV58256391; called by muse, mutect2, varscan2
- ALPK2 | c.3572C>T p.T1191M | Missense Mutation (SNP) | VAF 141/252 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs532039083, COSV64492907; called by muse, mutect2
- AMELX | c.133A>C p.I45L | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100497416; called by muse, mutect2
- ANKMY1 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs570625017, COSV56032002; called by muse, mutect2, varscan2
- ASB6 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs776601036, COSV52965505; called by muse, mutect2, varscan2
- B4GALT2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1312790665, COSV100530561; called by muse, mutect2
- BCORL1 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1167221282, COSV54408411; called by muse, mutect2, varscan2
- CARMIL1 | c.3230G>T p.R1077L | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV61524444; called by muse, mutect2, varscan2
- CHRM3 | c.509T>A p.I170N | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55106233; called by muse, mutect2, varscan2
- CLSPN | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 77/793 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99230465; called by muse, mutect2
- CSNK2A1 | c.178A>C p.T60P | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV53937912; called by muse, mutect2, varscan2
- CUX1 | c.2387C>A p.P796H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.215); catalogued as COSV52899052, COSV52917386; called by muse, mutect2, varscan2
- CUX1 | c.3793C>T p.Q1265* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as COSV52917398; called by muse, mutect2, varscan2
- DDX1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs1313727702, COSV51843820; called by muse, mutect2, varscan2
- DGAT2L6 | c.1008T>G p.I336M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100283869, COSV60718874; called by muse, mutect2, varscan2
- DIS3L | c.1258C>G p.L420V (on ENST00000319212 / NM_001143688.3; = p.L337V on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as COSV100054989; called by muse, mutect2
- DNAH9 | c.8072T>C p.F2691S | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52378768; called by muse, mutect2, varscan2
- EZR | c.1545G>C p.E515D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.363); catalogued as COSV51915609; called by muse, mutect2, varscan2
- F5 | c.2478G>C p.E826D | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs766402580, COSV63128932; called by muse, mutect2, varscan2
- H2BC14 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60798884; called by muse, mutect2, varscan2
- IL26 | c.432T>G p.I144M | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.694); catalogued as COSV57490187; called by muse, mutect2, varscan2
- ITPR3 | c.7377G>T p.L2459F | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100953597; called by muse, mutect2
- KAT14 | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV66609423; called by muse, mutect2, varscan2
- KMT2A | c.6076A>G p.M2026V | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs782378796, COSV100628217; called by muse, mutect2
- KRTAP13-1 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV62662983, COSV62664478; called by muse, mutect2, varscan2
- LDHA | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV57042843, COSV99908318; called by muse, mutect2, varscan2
- LRRIQ1 | c.1745A>T p.K582M | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV101279697; called by muse, mutect2
- MSGN1 | c.371A>G p.Q124R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV99808691; called by muse, mutect2, varscan2
- MTMR8 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.308); catalogued as rs1322671566, COSV100878284, COSV66396488; called by muse, mutect2, varscan2
- MYH8 | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV67973292; called by muse, mutect2, varscan2
- NELL2 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418976; called by muse, mutect2
- OR4C13 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.075); catalogued as rs782328583, COSV73648958; called by muse, mutect2, varscan2
- OR4M1 | c.529T>G p.Y177D | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100270995; called by muse, mutect2
- PARP1 | c.2683A>G p.I895V | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.161); catalogued as COSV64692372; called by muse, mutect2, varscan2
- PCK1 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100100062, COSV60127429; called by muse, mutect2
- PDCD11 | c.4799G>A p.R1600Q | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); catalogued as rs771155545, COSV53298067; called by muse, mutect2, varscan2
- PIAS2 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1357799772, COSV61342310; called by muse, mutect2, varscan2
- PLEKHH1 | c.4036G>A p.D1346N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.192); catalogued as COSV53615298; called by muse, mutect2, varscan2
- PRRT3 | c.1061T>C p.V354A | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV55978713; called by muse, mutect2, varscan2
- PYGB | c.1340T>C p.V447A | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV53823319; called by muse, mutect2, varscan2
- RGS7 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV58538555; called by muse, mutect2
- RNF146 | c.590C>T p.S197F (on ENST00000368314 / NM_001242850.2; = p.S196F on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV58934417; called by muse, mutect2, varscan2
- RNF213 | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV100173192; called by muse, mutect2
- SDAD1 | c.1668C>A p.F556L | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.39); catalogued as COSV62403906; called by muse, mutect2, varscan2
- SEC16A | c.3089C>G p.S1030C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as COSV99256696; called by muse, mutect2
- SEC31A | c.1987G>A p.D663N (on ENST00000355196 / NM_001318120.1; = p.D624N on NM_016211.4) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1490558971, COSV52352404; called by muse, mutect2, varscan2
- SEMA3D | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs771107222, COSV52394159; called by muse, mutect2, varscan2
- SERAC1 | c.1330C>G p.P444A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65598140; called by muse, mutect2, varscan2
- SI | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100013882, COSV100014430, COSV52265616; called by muse, mutect2
- SLC12A8 | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV100101974, COSV100103067; called by muse, mutect2
- SLC26A8 | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV62887823; called by muse, varscan2
- SUCLA2 | c.1028-1G>C p.X343_splice (on ENST00000643023; = p.X322_splice on NM_003850.3) | Splice Site (SNP) | VAF 7/149 reads (5%) | catalogued as COSV101074746; called by muse, mutect2
- SYNE2 | c.13018G>T p.D4340Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV59971880; called by muse, mutect2, varscan2
- TAP1 | c.1737A>T p.L579F | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV100841121, COSV100841134; called by muse, mutect2
- TDP2 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100593586; called by muse, mutect2
- THBS2 | c.2881A>G p.N961D | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as COSV64682426; called by muse, mutect2, varscan2
- TNIK | c.2848G>A p.V950I | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.195); catalogued as rs201681163, COSV52676546; called by muse, mutect2, varscan2
- TTLL3 | c.2468C>A p.S823* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as COSV59616013; called by muse, mutect2, varscan2
- TTN | c.3191T>A p.M1064K (on ENST00000591111; = p.M1018K on NM_003319.4) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | PolyPhen possibly damaging (0.73); catalogued as COSV60374334; called by muse, mutect2, varscan2
- UBXN1 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV53658865; called by muse, mutect2, varscan2
- VWA3B | c.2516A>G p.D839G | Missense Mutation (SNP) | VAF 8/286 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV101345964; called by muse, mutect2
- WDR64 | c.1352C>G p.P451R | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63800960; called by muse, mutect2, varscan2
- ZBTB3 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV67361906; called by muse, mutect2, varscan2
- ZNF132 | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV99571021; called by muse, mutect2
- ZNF302 | c.626C>G p.S209* (on ENST00000627982; = p.S130* on NM_018443.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/242 reads (4%) | catalogued as COSV101416443; called by muse, mutect2
- ZNF43 | c.1619G>C p.C540S | Missense Mutation (SNP) | VAF 68/416 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61686230; called by muse, mutect2, varscan2
- ZNF527 | c.1032C>A p.H344Q | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100648705; called by muse, mutect2
- ZNF808 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100707826; called by muse, mutect2
- ADAM10 | c.1031_1041del p.C344* | Frame Shift Del (DEL) | VAF 17/109 reads (16%) | called by mutect2, pindel, varscan2
- ATP2C2 | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2
- VN1R1 | c.609del p.N203Kfs*28 | Frame Shift Del (DEL) | VAF 37/205 reads (18%) | called by mutect2, pindel, varscan2
- ADCY2 | c.873C>A p.I291= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV57902675; called by muse, mutect2, varscan2
- AGK | c.1191G>A p.V397= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV100814554; called by muse, mutect2
- CDH26 | c.946T>C p.L316= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs749615978, COSV54856140; called by muse, mutect2, varscan2
- CFAP251 | c.318C>A p.S106= | Silent (SNP) | VAF 23/196 reads (12%) | catalogued as COSV55840865; called by muse, mutect2, varscan2
- FAM151B | c.99C>T p.I33= | Silent (SNP) | VAF 10/201 reads (5%) | catalogued as COSV99971626; called by muse, mutect2
- FAM155A | c.645C>G p.L215= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as COSV65584481; called by muse, mutect2, varscan2
- GANC | c.1632C>T p.Y544= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs778286123, COSV100530753; called by muse, mutect2
- HEATR1 | c.4314T>G p.A1438= | Silent (SNP) | VAF 9/191 reads (5%) | catalogued as COSV100857514; called by muse, mutect2
- MYO3B | c.2409A>G p.Q803= | Silent (SNP) | VAF 7/151 reads (5%) | catalogued as COSV100509439; called by muse, mutect2
- NSD3 | c.3186G>A p.E1062= | Silent (SNP) | VAF 39/179 reads (22%) | catalogued as COSV57674547; called by muse, mutect2, varscan2
- PADI3 | c.1374C>A p.P458= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV64934337; called by muse, mutect2
- ROPN1 | c.129C>G p.A43= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV51741245; called by muse, mutect2, varscan2
- SLC7A9 | c.108C>T p.I36= | Silent (SNP) | VAF 33/230 reads (14%) | catalogued as COSV50082757, COSV50095396; called by muse, mutect2, varscan2
- SYN3 | c.1653C>T p.T551= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV60517289; called by muse, mutect2, varscan2
- THBS1 | c.3321C>T p.A1107= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV52956176; called by muse, mutect2, varscan2
- TMPRSS11E | c.858T>G p.P286= | Silent (SNP) | VAF 12/364 reads (3%) | catalogued as COSV100542265; called by muse, mutect2
- TMTC4 | c.1362G>A p.T454= (on ENST00000376234 / NM_001350577.2; = p.T473= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/231 reads (20%) | catalogued as rs747247632, COSV60893737; called by muse, mutect2, varscan2
- TTC37 | c.4482C>G p.R1494= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV62457109; called by muse, mutect2, varscan2
- ZNF16 | c.594T>A p.G198= | Silent (SNP) | VAF 13/240 reads (5%) | catalogued as COSV99429474; called by muse, mutect2
- ZNF184 | c.1569T>G p.T523= | Silent (SNP) | VAF 25/243 reads (10%) | catalogued as COSV53005877; called by muse, mutect2, varscan2
- OBSCN | c.4585+2760C>G | Intron (SNP) | VAF 12/85 reads (14%) | catalogued as COSV52834838; called by muse, mutect2, varscan2
